Somatic mutation profile of tumor specimen TCGA-N6-A4VF-01A (aliquot TCGA-N6-A4VF-01A-31D-A28R-08) from TCGA case TCGA-N6-A4VF, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Age at diagnosis: 51.5 years (18,806 days).
Specimen TCGA-N6-A4VF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c557032-39b1-4a7a-894e-5e1744a61793.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N6-A4VF-11A (Solid Tissue Normal), aliquot TCGA-N6-A4VF-11A-11D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d213efff-f2ac-4a05-8e6f-97d64387ee89

The open-access MAF lists 46 somatic variants for this specimen: 38 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 7, Frame Shift Ins 2, Nonsense Mutation 2, Splice Site 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 31/67 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 23/66 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASXL3 | c.4471G>A p.V1491I | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs751537958, COSV99326181; called by muse, mutect2, varscan2
- CLIP2 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 78/183 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs782548580; called by muse, mutect2, varscan2
- DSCAML1 | c.1270C>T p.R424C (on ENST00000321322; = p.R364C on NM_020693.4) | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs766124348, COSV58391488; called by muse, mutect2, varscan2
- EPB41L3 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV59452165; called by muse, mutect2, varscan2
- EPHB1 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 98/220 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs1330628001, COSV67671236; called by muse, mutect2, varscan2
- ITIH4 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as rs772291690, COSV99819331; called by muse, mutect2, varscan2
- KCNA4 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs1406027339, COSV60251112; called by muse, mutect2, varscan2
- MAML2 | c.2417G>A p.R806K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV73264368; called by muse, mutect2, varscan2
- MAP7 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766447512; called by muse, mutect2, varscan2
- MBIP | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as rs140089260, COSV59253560; called by muse, mutect2, varscan2
- MEN1 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs750112288, COSV53648857; ClinVar: uncertain significance / benign / likely benign; called by muse, mutect2, varscan2
- MYH7B | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs763470548, COSV53425144; called by muse, mutect2, varscan2
- NAV3 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs754639465; called by muse, mutect2, varscan2
- PTPN5 | c.1080+1G>A p.X360_splice | Splice Site (SNP) | VAF 36/96 reads (38%) | catalogued as rs724159938; called by muse, mutect2, varscan2
- SCRIB | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1028275538, COSV100253109; called by muse, mutect2, varscan2
- SOX4 | c.1376C>G p.S459W | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55192783; called by muse, mutect2
- TMEM215 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61363610; called by muse, mutect2, varscan2
- TP53 | c.1007_1011dup p.F338Sfs*9 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | catalogued as COSV53239551; called by mutect2, pindel
- UGT1A6 | c.234T>G p.Y78* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as rs1048987218; called by muse, mutect2, varscan2
- ZC3H10 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.981); catalogued as COSV57768258; called by muse, mutect2, varscan2
- AGRN | c.4738dup p.R1580Pfs*9 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- AP5M1 | c.44C>A p.T15N | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMWD | c.1656_1658del p.G553del | In Frame Del (DEL) | VAF 22/56 reads (39%) | called by pindel, varscan2
- ESX1 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FTL | c.491A>C p.E164A | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- GRIA3 | c.2393G>A p.W798* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- ILF3 | c.77A>T p.E26V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNJ9 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LEPR | c.2033G>A p.R678K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LRRC4C | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRN4 | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- OR8A1 | c.635C>A p.T212K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- REV3L | c.8884C>T p.L2962F | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIC8B | c.880G>C p.D294H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZAN | c.1504C>T p.H502Y | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ARHGAP9 | c.597C>A p.R199= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV62724241; called by muse, mutect2, varscan2
- BMP6 | c.672C>T p.Y224= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as rs375867934; called by muse, mutect2, varscan2
- CASZ1 | c.1620C>T p.H540= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs575650869; called by muse, mutect2, varscan2
- F10 | c.1092C>T p.F364= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as rs772703608, COSV65021107; called by muse, mutect2, varscan2
- HSPG2 | c.10524C>T p.F3508= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs991985128, COSV101013564; called by muse, mutect2, varscan2
- PCDHGB3 | c.1662C>T p.D554= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs1228124665; called by muse, mutect2, varscan2
- SALL3 | c.2289C>T p.G763= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as rs751203516, COSV73305763; called by muse, mutect2, varscan2
- HM13 | c.1035-968C>G | Intron (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
